Somatic mutation profile of tumor specimen TCGA-VM-A8C9-01A (aliquot TCGA-VM-A8C9-01A-11D-A36O-08) from TCGA case TCGA-VM-A8C9, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 37.4 years (13,663 days).
Specimen TCGA-VM-A8C9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e31c2fb-cd32-4712-a555-2b17014cec71.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VM-A8C9-10A (Blood Derived Normal), aliquot TCGA-VM-A8C9-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/abe948f4-1bf5-4100-b03b-19f450459c25

The open-access MAF lists 7 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IGLL5 | c.389A>G p.N130S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.117); catalogued as rs1474877942, COSV101138893, COSV104433405; called by muse, mutect2
- PCDH10 | c.1145T>C p.V382A | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.995); catalogued as COSV99994742; called by muse, mutect2
- PIK3CA | c.2133G>T p.K711N | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55968415; called by muse, mutect2, varscan2
- SLC17A4 | c.1030T>A p.C344S | Missense Mutation (SNP) | VAF 4/90 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as COSV100930696; called by muse, mutect2
- SORT1 | c.1273A>G p.I425V | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.006); catalogued as rs775647545, COSV99861258; called by muse, mutect2, varscan2
- NEURL2 | c.798G>A p.R266= | Silent (SNP) | VAF 3/49 reads (6%) | catalogued as COSV51941206; called by muse, mutect2
- PARP9 | c.951G>A p.L317= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as rs991563120, COSV100831301; called by muse, mutect2
